Somatic mutation profile of tumor specimen 0DPL7N from CCDI case PBCBVP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Subependymal giant cell astrocytoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 12.2 years (4,448 days).
Specimen 0DPL7N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5414856d-bd6b-449b-bdcc-62d40c4223bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPL7F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/887bb5af-15dc-4a8c-8c53-d7d49a555332

The open-access MAF lists 21 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 8, Missense Mutation 6, 5'UTR 2, 3'UTR 2, Silent 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC2 | c.3412C>T p.R1138* | Nonsense Mutation (SNP) | VAF 117/237 reads (49%) | catalogued as rs45451497, CM992687, COSV54761190; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 53/638 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs371439495; called by muse, mutect2
- SREBF1 | c.2588T>C p.M863T | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs375687681; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 29/880 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- NEURL3 | c.150C>A p.F50L | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- TTC33 | c.313T>C p.S105P | Missense Mutation (SNP) | VAF 151/517 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ZXDB | c.660C>G p.H220Q | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HUS1B | c.492G>A p.T164= | Silent (SNP) | VAF 130/390 reads (33%) | called by muse, mutect2, varscan2
- ATP6V1E1 | c.530+52C>A | Intron (SNP) | VAF 15/288 reads (5%) | called by muse, mutect2
- CFAP74 | c.3388-81C>A | Intron (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- DCST2 | c.1871-99C>A | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- DIO3 | c.*60C>A | 3'UTR (SNP) | VAF 4/47 reads (9%) | catalogued as rs1566744816; called by muse, mutect2
- DLX6 | c.-70C>A | 5'UTR (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- KMT2B | c.6960-10G>C | Intron (SNP) | VAF 56/198 reads (28%) | called by muse, mutect2, varscan2
- LRATD2 | c.-26C>A | 5'UTR (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- MAP3K12 | c.-37-53C>A | Intron (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- MBTD1 | c.*67C>A | 3'UTR (SNP) | VAF 6/101 reads (6%) | catalogued as COSV70583072; called by muse, mutect2
- NEXMIF | c.4458-72C>A | Intron (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- RIT1 | c.237+22T>C | Intron (SNP) | VAF 44/256 reads (17%) | catalogued as rs999921264; called by muse, mutect2, varscan2
- RPF1 | c.366+90C>A | Intron (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- SERPINB6 | chr6:2971051 G>T | 5'Flank (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
